Somatic mutation profile of tumor specimen MP2PRT-PARHEM-TMP1-A (aliquot MP2PRT-PARHEM-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARHEM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 6.9 years (2,524 days).
Specimen MP2PRT-PARHEM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a93e1d71-6dd2-416f-a9f2-134f9ba7fb57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARHEM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARHEM-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b56eb29c-ba42-4dd7-b5e3-ede7abb5514f

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6orf89 | c.728G>A p.R243H (on ENST00000373685; = p.R250H on NM_152734.4) | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs144834171; called by muse, varscan2
- CPS1 | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 108/241 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776047286, COSV51805628; called by muse, varscan2
- YEATS2 | c.3097G>C p.G1033R | Missense Mutation (SNP) | VAF 120/270 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59370037; called by muse, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 155/336 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, varscan2
- KMT2D | c.15839_15840delinsCCGTTCCCCTCCCGGA p.M5280Tfs*14 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by pindel, varscan2*
- PPRC1 | c.592-2_592del p.X198_splice | Splice Site (DEL) | VAF 7/138 reads (5%) | called by mutect2, pindel*
- TMTC3 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); called by muse, varscan2
